Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABL8, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABL8-TTP1-C (Primary Tumor).

[page 1 of 2]
Previous exams

Previous exams exist.

Clinical Data and Diagnostic Questions

Previous biopsy : right peripheral B3: non-small cell lung carcinoma, most probably adenocarcinoma.

Material description

1. Lymph node n. 4/ surgical biopsy
2. Lymph node n. 11/ surgical biopsy
3. Lymph node n. 11/ surgical biopsy
4. Lymph node n. 12 (lobar left bronchus) / surgical biopsy
5. Upper lobe, right lung / surgical sample
6. Lymph node n. 10// surgical biopsy

ICD-0-3

adenocarcinoma, NOS 8140/3
Site: (R) lung, upper lobe C34.1

ICD-10

C 34.11

Macro description

1. Blackish nodular fragment of 4 x 2 mm
2. Blackish nodular fragment of 2 x 2 mm
3. Blackish nodular fragment of 3 x 1 mm
4. Three tiny blackish fragments
5. Pulmonary lobe of 12 x 10 x 5 mm. In median region it contains nodular neoformation, soft margins of 3,5 x 2,5 x 1,5 cm of greyish coloring, which apparently doesn't infiltrate the pleural surface. Apparently free of neoplasm the bronchial lobar section and the hilum vessels, where we isolate also brownish lymph node of 10 x 5 mm. No macroscopic lesions in the pulmonary residual parenchyma.
6. Two blackish fragments, the biggest of which of 4 x 2 mm

fw
2/12/16

Micro description

- 1.2.3.6. The lymph nodes n. 4, n. 11 and n. 10 are anthracotic and negative for neoplasm
4. The lymph node n. 12 is site of focal metastasis with the morphological characters as described under 5.
5. The numerous samples performed show neoplastic malignant epithelial process with the characters of the adenocarcinoma. The elements place themselves in tubules, glands, nests and sometimes aggregates sometimes also solid: there are micropapillary areas and areas of bronchiolo-alveolar carcinoma growth pattern. The neoplasm diffusely infiltrates the pulmonary parenchyma; neoplastic nests are in the surrounding pulmonary parenchyma; numerous images of vascular invasions mainly intratumoral. No infiltration of the above visceral pleura. The neoplasm determines submassive metastasis for contiguity with a hilar lymph node. The index of nuclear proliferation determinate with antibody MIB1 (KI 67) is

[page 2 of 2]
10%; the protein p53 is expressed in strewn neoplastic nucleus. Bronchus of section negative for neoplasm. The pulmonary not neoplastic parenchyma shows lymphoid reactive aggregates and anthracotic blackish pigment.

Conclusions and histopathological diagnosis

1.2.3.6 Lymph nodes anthracosis

4. Lymph node metastasis of adenocarcinoma

5. Moderately differentiated adenocarcinoma with micropapillary areas and areas a pattern of growth of type bronchiolo-alveolar carcinoma. Vascular invasion intratumoral and peritumoral. Lymph node hilar metastasis for contiguity. Bronchus of section negative for neoplasm.

Staging *pTNM*: MISSING

Source: NCI Genomic Data Commons file 874fde63-34ec-4ea5-8613-fa70599b8722 (CDDP-ABL8-TTP1.BD3B78D3-F9A4-4E01-A263-BDC0B95D8DBA.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).